MMRF case MMRF_1478 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ee494e20-2254-4eee-a452-149d28ca330c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 48 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 48.1 years (17,563 days); ISS stage: III; Days to last known disease status: 1,337 days (3.7 years); Days to last follow up: 1,337 days (3.7 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 73 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 7 days; Days to treatment end: 7 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 21 days; Days to treatment end: 76 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone + Doxorubicin + Lenalidomide + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 91 days; Days to treatment end: 94 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 118 days; Days to treatment end: 118 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 119 days; Days to treatment end: 119 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 305 days; Days to treatment end: 308 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Allogeneic; Regimen or line of therapy: First line of therapy; Days to treatment start: 311 days; Days to treatment end: 311 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 675 days (1.8 years); Days to treatment end: 675 days (1.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 7.1 g/dL; Immunoglobulin G 103 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 10.1 µg/mL; Lactate Dehydrogenase 8.54 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 11.8 ×10⁹/L; Absolute Neutrophil 7.5 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 110 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.23 mmol/L; Albumin 31 g/L; Total Protein 11 g/dL; Glucose 5.06 mmol/L; C-Reactive Protein 0.9 mg/dL.
- Day 91 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 13.9 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.65 g/L; Lactate Dehydrogenase 7.72 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 8.9 ×10⁹/L; Absolute Neutrophil 6.71 ×10⁹/L; Platelets 324 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 4.84 mmol/L.
- Day 169 (ECOG 1): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.108 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.14 mg/dL; Immunoglobulin G 7.02 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 2.55 µg/mL; Lactate Dehydrogenase 10.5 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 290 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.3 g/dL; Glucose 5.06 mmol/L.
- Day 283 (ECOG 1): M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.66 mg/dL; Immunoglobulin G 9.43 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.21 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 284 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.53 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 5.06 mmol/L.
- Day 349 (ECOG 2): Lactate Dehydrogenase 11.9 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 19.2 ×10⁹/L; Absolute Neutrophil 17.3 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 7.2 g/dL; Glucose 7.65 mmol/L.
- Day 442 (ECOG 1): M Protein 0.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 4.89 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 2.78 µg/mL; Lactate Dehydrogenase 7.77 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 241 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 4.84 mmol/L.
- Day 538 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.541 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 4.88 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.78 g/L; Lactate Dehydrogenase 4.67 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 6 g/dL; Glucose 4.9 mmol/L.
- Day 636 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 5.34 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 1.48 g/L; Lactate Dehydrogenase 8.13 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.38 mmol/L; Albumin 45 g/L; Total Protein 6.6 g/dL; Glucose 4.84 mmol/L.
- Day 735 (ECOG 0): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 5.95 g/L; Immunoglobulin A 1.2 g/L; Immunoglobulin M 1.74 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.35 mmol/L; Albumin 47 g/L; Total Protein 6.6 g/dL; Glucose 4.79 mmol/L.
- Day 825 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.52 mg/dL; Immunoglobulin G 7.56 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 1.88 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 46 g/L; Total Protein 6.8 g/dL; Glucose 5.12 mmol/L.
- Day 930 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.35 mg/dL; Immunoglobulin G 7.97 g/L; Immunoglobulin A 1.67 g/L; Immunoglobulin M 1.71 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 2.25 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.61 mmol/L.
- Day 1,021 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.78 mg/dL; Immunoglobulin G 8.23 g/L; Immunoglobulin A 2.23 g/L; Immunoglobulin M 2.54 g/L; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 6.9 g/dL; Glucose 5.83 mmol/L.
- Day 1,112 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.81 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.11 mg/dL; Immunoglobulin G 7.53 g/L; Immunoglobulin A 2.85 g/L; Immunoglobulin M 1.93 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.23 mmol/L.
- Day 1,197 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.19 mg/dL; Immunoglobulin G 8.2 g/L; Immunoglobulin A 2.83 g/L; Immunoglobulin M 2.23 g/L; Lactate Dehydrogenase 6.2 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.48 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 5.06 mmol/L.
- Day 1,239 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.19 mg/dL; Immunoglobulin G 8.2 g/L; Immunoglobulin A 2.83 g/L; Immunoglobulin M 2.23 g/L; Lactate Dehydrogenase 2.27 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.35 mmol/L; Albumin 46 g/L; Total Protein 7.2 g/dL; Glucose 5.12 mmol/L.
- Day 1,337 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.67 mg/dL; Immunoglobulin G 8.01 g/L; Immunoglobulin A 2.59 g/L; Immunoglobulin M 2 g/L; Lactate Dehydrogenase 2.47 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 47 g/L; Total Protein 7.2 g/dL; Glucose 5.67 mmol/L.

Other clinical attributes
- Day 1: Weight: 100 kg; Height: 162 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1478_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1478_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
